FM case AD13356 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/3d58d8b0-a842-44eb-afb9-784ee9e4e329

Female, 53.0 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3); specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
